Somatic mutation profile of tumor specimen BA2709D (aliquot aq-BA2709D) from BEATAML1.0 case 2346, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.1 years (10,976 days).
Specimen BA2709D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f7a091-0ae1-4d48-8bfe-bbd32eca63b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2530D (Solid Tissue Normal), aliquot aq-BA2530D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bf76a2b-1756-47be-833f-3570585cbfc4

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOXA3 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57825747; called by muse, mutect2
- EDEM2 | c.971G>T p.S324I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2
- GEMIN4 | c.2274G>T p.W758C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NHLH1 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- NLN | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.279); called by muse, mutect2
- TBC1D10C | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.053); called by muse, mutect2
- TCAIM | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2
- ONECUT1 | c.747G>T p.P249= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
